Somatic mutation profile of tumor specimen TCGA-BP-4971-01A (aliquot TCGA-BP-4971-01A-01D-1462-08) from TCGA case TCGA-BP-4971, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 40.2 years (14,675 days).
Specimen TCGA-BP-4971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a1e27fb-8d64-41eb-bd42-47f63b820c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4971-11A (Solid Tissue Normal), aliquot TCGA-BP-4971-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/264bf3e9-632f-4083-9a67-f8f79b3817b0

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 27, Silent 14, Frame Shift Del 4, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57923483; called by muse, mutect2
- ANKH | c.1462A>T p.R488* | Nonsense Mutation (SNP) | VAF 68/336 reads (20%) | catalogued as COSV52476921; called by muse, mutect2, varscan2
- ANO3 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as COSV56780466; called by muse, mutect2, varscan2
- CAMSAP2 | c.1902G>A p.M634I (on ENST00000236925 / NM_001297707.2; = p.M623I on NM_203459.3) | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV52666854; called by muse, mutect2, varscan2
- CAMSAP2 | c.1903G>T p.D635Y (on ENST00000236925 / NM_001297707.2; = p.D624Y on NM_203459.3) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52666877; called by muse, mutect2, varscan2
- DPP6 | c.382A>C p.K128Q (on ENST00000377770 / NM_001364500.2; = p.K66Q on NM_001936.5) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.788); catalogued as COSV59597911; called by muse, mutect2, varscan2
- FRAS1 | c.6047T>C p.L2016P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV53588989; called by muse, mutect2, varscan2
- KBTBD8 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.222); catalogued as COSV55126638; called by muse, mutect2, varscan2
- KEL | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV62333246; called by muse, mutect2, varscan2
- LMTK2 | c.784del p.L262Cfs*5 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV51997915; called by mutect2, pindel, varscan2
- MUC21 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.134); catalogued as rs1191398271, COSV100888908, COSV66220036; called by muse, mutect2, varscan2
- MXRA5 | c.8035C>A p.L2679M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV54223736; called by muse, mutect2, varscan2
- NOX4 | c.763T>A p.F255I | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54446854; called by muse, mutect2, varscan2
- NT5DC3 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 86/440 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV67321217; called by muse, mutect2, varscan2
- OR4K15 | c.542C>T p.T181I (on ENST00000305051; = p.T157I on NM_001005486.1) | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs199987412; called by muse, mutect2, varscan2
- PCDHA5 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV65349303; called by muse, mutect2, varscan2
- POC5 | c.1155G>T p.K385N (on ENST00000428202 / NM_001099271.2; = p.K360N on NM_152408.2) | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV66841504; called by muse, mutect2, varscan2
- PTCHD1 | c.1013-1G>C p.X338_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV65059016; called by muse, mutect2, varscan2
- SPG21 | c.899G>T p.S300I | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV52602064; called by muse, mutect2, varscan2
- SRSF4 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65694055; called by muse, mutect2
- SYTL2 | c.2140T>G p.L714V (on ENST00000528231 / NM_001162951.2; = p.L690V on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60355810; called by muse, mutect2, varscan2
- TERT | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as rs1413965241, COSV57199304, COSV57199357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNN | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53421608; called by muse, mutect2, varscan2
- TRMT6 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239559496, COSV52542590; called by muse, varscan2
- TRRAP | c.10426G>C p.A3476P (on ENST00000359863 / NM_001244580.1; = p.A3447P on NM_003496.3) | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62838830; called by muse, mutect2, varscan2
- VPS41 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56068318; called by muse, mutect2, varscan2
- WNK2 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52931003; called by muse, mutect2, varscan2
- ZNF274 | c.1357C>T p.R453C (on ENST00000610905; = p.R348C on NM_016324.3) | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.818); catalogued as rs757676940, COSV58762932, COSV58764086; called by muse, mutect2, varscan2
- ZNF337 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53320176; called by muse, mutect2, varscan2
- ZNF407 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs774957030, COSV55242714; called by muse, mutect2, varscan2
- ALB | c.1303del p.Y435Tfs*14 | Frame Shift Del (DEL) | VAF 27/171 reads (16%) | called by mutect2, pindel, varscan2
- BAP1 | c.546_559del p.L183Gfs*5 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel
- KRT72 | c.1144del p.L382* | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- ASMT | c.519C>T p.T173= | Silent (SNP) | VAF 41/238 reads (17%) | catalogued as rs773168368, COSV67109536; called by muse, mutect2, varscan2
- C17orf75 | c.318G>T p.G106= | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as COSV56752204; called by muse, mutect2, varscan2
- DNAJC2 | c.1209A>T p.T403= | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as rs1235487346, COSV50789487; called by muse, mutect2, varscan2
- DPP3 | c.660T>A p.L220= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV64755869; called by muse, mutect2, varscan2
- GIGYF2 | c.2094T>C p.A698= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV65246501; called by muse, mutect2, varscan2
- KAT2B | c.1029C>T p.L343= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs751533877, COSV55426546; called by muse, mutect2, varscan2
- MEAK7 | c.1005G>A p.V335= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1483227567, COSV59143125; called by muse, mutect2, varscan2
- MYH11 | c.2925G>A p.T975= | Silent (SNP) | VAF 13/356 reads (4%) | catalogued as rs566872637, COSV55542933; called by muse, mutect2
- PRKD2 | c.2256C>T p.N752= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs748749845, COSV52184520; called by muse, mutect2, varscan2
- PZP | c.2103T>C p.Y701= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs750273929, COSV54354431; called by muse, mutect2, varscan2
- RPL22L1 | c.342T>C p.D114= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55556578; called by muse, mutect2, varscan2
- RSF1 | c.3984G>A p.R1328= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as COSV57836438; called by muse, mutect2, varscan2
- TRAFD1 | c.759A>G p.Q253= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV57503264; called by muse, mutect2, varscan2
- WDR18 | c.507T>A p.S169= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52120766; called by muse, mutect2, varscan2
